Gene-level copy-number profile of tumor specimen TCGA-EK-A2RJ-01A from TCGA case TCGA-EK-A2RJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 51.1 years (18,664 days).
Specimen TCGA-EK-A2RJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.218ca6bd-a262-4e8b-a209-5cc9e5e15d88.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EK-A2RJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b5e7c1d9-a466-43fd-9303-8135253e1019

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 7; copy number 2: 1,073; copy number 3: 5,536; copy number 4: 17,162; copy number 5: 15,771; copy number 6: 7,347; copy number 7: 6,685; copy number 8: 2,582; copy number 9: 2,437; copy number 11: 640; copy number 15: 579.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EK-A2RJ-01A-11D-A18H-01): tumor purity 0.5, ploidy 2.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,656 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–155,934,413, 579 genes, copy number 15 (within-gene range 6–15) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 9 (broad region; genes not listed).
- chr7:75,769,533–159,233,377, 1,592 genes, copy number 9 (broad region; genes not listed).
- chr19:22,832,291–44,954,007, 775 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
